Surgical pathology report (de-identified scan), TCGA case TCGA-QK-A6IJ, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-A6IJ-01A (Primary Tumor).

[page 1 of 5]
Document Type: Anat Path Reports
Document Date:
Document Status: UUID:53C15899-4EC9-4182-945C-DA91A2536E42
Document Title: TCGA-QK-A61J-01A-PR Redacted
Performed By:
Verified By:
Encounter info:

ICD-O-3
Carcinoma, squamous
cell NOS 8070/3 NOS
Site: Floor of mouth
104.9
JW 6/12/13

*** Final Report ***

(Verified)

Patient Name: [REDACTED] Acc #: [REDACTED]
MRN: [REDACTED] DOB: [REDACTED] Head and Neck
Location: [REDACTED] Gender: M Collected:
Client: Received:
Submitting Phys: Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

A. FLOOR OF MOUTH, LEFT, WIDE LOCAL EXCISION, A1FS:

- INVASIVE SQUAMOUS CELL CARCINOMA, POORLY DIFFERENTIATED (2.2 X 1.8 X 0.4 CM).
- ALL FINAL SURGICAL MARGINS (INCLUDES PARTS B, C, E, F) NEGATIVE FOR HIGH GRADE GRADE DYSPLASIA AND INVASIVE CARCINOMA.
- SEE SYNOPTIC REPORT.

B. FLOOR OF MOUTH, SUPERIOR MARGIN, EXCISION, B1FS:

- FOCAL MILD EPITHELIAL DYSPLASIA.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

C. FLOOR OF MOUTH, INFERIOR MARGIN, EXCISION, C1FS:

- ULCERATED SQUAMOUS MUCOSA.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

D. FLOOR OF MOUTH, ANTERIOR MARGIN, EXCISION, D1FS:

- FOCAL HIGH-GRADE SQUAMOUS DYSPLASIA.
- DYSPLASIA BEST SEEN ON FROZEN SECTION SLIDES.
- SEE PART F FOR FINAL MARGIN STATUS.

E. FLOOR OF MOUTH, POSTERIOR MARGIN, EXCISION, E1FS:

- SQUAMOUS MUCOSA WITH REACTIVE LYMPHOID AGGREGATES.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

F. FLOOR OF MOUTH, NEW ANTERIOR MARGIN, EXCISION, F1FS:

- SQUAMOUS MUCOSA WITH REACTIVE LYMPHOID AGGREGATES.
- NEGATIVE FOR HIGH GRADE DYSPLASIA AND INVASIVE CARCINOMA.

G. LYMPH NODES, LEFT LEVEL I, NECK DISSECTION:

- SEVEN LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/7).
- SALIVARY GLAND PARENCHYMA WITH CHRONIC SIALADENITIS.

W 6/11/13

HPV A Discrepancy		
Primary Tumor Site History		
Primary/Synchronous Primary Tumor		

[page 2 of 5]
H. LYMPH NODES, LEFT LEVEL II, NECK DISSECTION:

- METASTATIC CARCINOMA IN ONE OF SEVEN LYMPH NODES (1/7).
- DEPOSIT MEASURES 1.7CM IN A LYMPH NODE MEASURING 2.5CM.

I. LYMPH NODES, LEFT LEVEL III, NECK DISSECTION:

- SIXTEEN LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/16).

J. LYMPH NODES, LEFT LEVEL IV, NECK DISSECTION:

- NINE LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/9).

K. LYMPH NODES, LEFT NECK, NECK DISSECTION:

- ONE LYMPH NODE NEGATIVE FOR METASTATIC CARCINOMA (0/1).

Electronically Signed by

Assisted by:

Synoptic Worksheet

A. Left floor of mouth lesion, single - anterior; double - inferior;:

Clinical History:	No neoadjuvant therapy
Specimen:	Floor of mouth, NOS
Received:	Fresh
Procedure:	Neck (lymph node) dissection: LEFT LEVELS I-IV Other: WIDE LOCAL EXCISION
Specimen Integrity:	Intact
Specimen Size:	Greatest dimension: 3.9 cm Additional dimension: 2.6 cm Additional dimension: 1.5 cm
Specimen Laterality:	Left
Tumor Site:	Floor of mouth, NOS
Tumor Focality:	Single focus
Tumor Size:	Greatest dimension: 2.2 cm
Tumor Thickness (pT1 and pT2 tumors):	Tumor thickness: 4 mm Measured from ulcerated surface
Tumor Description:	Exophytic Ulcerated
Macroscopic Extent of Tumor:	Confirmed with hyoglossus muscle involvement was ABSENT at time of surgery.
Histologic Type:	Squamous cell carcinoma, conventional
Histologic Grade:	G3: Poorly differentiated
Microscopic Tumor Extension:	Superficial skeletal muscle bundles.
Margins:	Margins uninvolved by invasive carcinoma Distance from closest margin: 3 Unit of measurement: mm Margin(s): Inferior Margins uninvolved by carcinoma in situ (includes moderate and severe dysplasia)
Treatment Effect:	Not identified
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Lymph Nodes, Extranodal Extension:	Not identified
Pathologic Staging (pTNM):	
TNM Descriptors:	Not applicable

[page 3 of 5]
Primary Tumor (pT):	pT2:Tumor more than 2 cm but not more than 4 cm in greatest dimension
Regional Lymph Nodes (pN):	pN1: Metastasis in a single ipsilateral lymph node, 3 cm or less in greatest dimension Number of regional lymph nodes examined: 40 Number of regional lymph nodes involved: 1 Size (greatest dimension) of the largest positive lymph node: 2.5 cm
Distant Metastasis (pM):	Not applicable
Additional Pathologic Findings:	None identified Inflammation (type): eosinophils

Clinical History

Left neck dissection. Lesion left floor of mouth, squamous cell carcinoma. WLE, left neck dissection, skin graft from thigh, possible primary closure.

Specimen(s) Received

A: Left floor of mouth lesion, single - anterior; double - inferior;
B: Superior margin
C: Inferior margin
D: Anterior margin
E: Posterior margin
F: New anterior margin
G: Left neck level 1
H: Left neck level 2
I: Left neck level 3
J: Left neck level 4
K: Left neck contents

Gross Description

Part A is received fresh labeled with the patient's name, medical record number and as "left floor of mouth lesion". The specimen consists of mucosa-lined soft tissue with the following dimensions: anterior-posterior 3.9 cm, inferior-superior 2.6 cm, medial-lateral 1.5 cm. There is a raised firm lesion involving the mucosa measuring 2.2 x 1.8 x 0.4 cm and related to the edges of the specimen as follows: deep 0.4 cm, superior 0.5 cm, inferior 0.3 cm, anterior approximately 0.5 cm, posterior approximately 0.5 cm. The specimen is inked as follows: anterior-orange, posterior-yellow, superior-blue, inferior-green, deep margin-black. Tissue is submitted to _____ The specimen is entirely submitted as described below. (Dictated by _____)

CASSETTE SUMMARY:

A1FS: Lesion and deep margin
A2: Anterior edge, superior, perpendicularly sectioned
A3: Anterior edge, inferior, perpendicularly sectioned
A4-A6: Central specimen, serially sectioned from anterior-to-posterior
A7: Posterior edge, superior, perpendicularly sectioned
A8: Posterior edge, middle, perpendicularly sectioned
A9: Posterior edge, inferior, perpendicularly sectioned

Part B is received fresh labeled with the patient's name, medical record number and as "superior margin FS". The specimen consists of a strip of mucosa-lined soft tissue measuring 3.5 x 0.6 x 0.2 cm. The specimen is entirely submitted in cassette B1FS. (Dictated by _____)

Part C is received fresh labeled with the patient's name, medical record number and as "inferior margin FS". The specimen consists of a strip of mucosa-lined soft tissue measuring 2.8 x 0.3 x 0.2 cm. The specimen is entirely submitted in cassette C1FS. (Dictated by _____)

[page 4 of 5]
Part D is received fresh labeled with the patient's name, medical record number and as "anterior margin FS". The specimen consists of a strip of mucosa-lined soft tissue measuring 2.0 x 0.4 x 0.2 cm. The specimen is entirely submitted in cassette D1FS. (Dictated by

Part E is received fresh labeled with the patient's name, medical record number and as "posterior margin FS". The specimen consists of multiple fragments of soft tissue measuring in aggregate 1.5 x 0.3 x 0.2 cm. The specimen is entirely submitted in cassette E1FS. (Dictated by

Part F was received fresh, labeled with the patient's name, medical record number and "new anterior margin, FS." The specimen consists of a strip of mucosa-lined soft tissue measuring 2.6 x 0.4 x 0.2 cm. The specimen is entirely submitted in cassette "F1FS." Dictated by

Part G is received fresh labeled with the patient's name, medical record number and as "left neck level 1". The specimen consists of a soft tissue measuring 5 x 3 x 1.8 cm. Multiple lymph nodes are identified ranging in size from 1.2 x 0.7 x 0.5 cm to 0.5 x 0.5 x 0.5 cm. A salivary gland measuring 3 x 3 x 1 cm is also present. Representative sections are submitted as described below. (Dictated by

CASSETTE SUMMARY:

G1: Two lymph nodes, whole
G2: Two lymph nodes, whole
G3-G7: Multiple lymph nodes, whole
G8: Representative salivary gland

Part H is received fresh labeled with the patient's name, medical record number and as "left neck level 2". The specimen consists of a soft tissue measuring 6 x 3 x 1.7 cm. A grossly malignant lymph node measuring 3.5 x 2.0 x 1.3 cm is present. Additional lymph nodes are identified ranging in size from 1.4 x 0.7 x 0.5 cm to 0.5 x 0.5 x 0.5 cm. Representative sections are submitted as described below. (Dictated by

CASSETTE SUMMARY:

H1, H2: Grossly malignant node, representative
H3: One lymph node, bisected
H4: Two lymph nodes, whole
H5: Two lymph nodes, whole

Part I is received fresh labeled with the patient's name, medical record number and as "left neck level 3". The specimen consists of a soft tissue measuring 4 x 3.5 x 1.5 cm. Multiple lymph nodes are identified ranging in size from 1.3 x 0.9 x 0.5 cm to 0.5 x 0.5 x 0.5 cm. Representative sections are submitted as described below. (Dictated by

CASSETTE SUMMARY:

I1: Three lymph nodes, whole
I2: One lymph node, bisected
I3: Three lymph nodes, whole
I4: Three lymph nodes, whole
I5: One lymph node, whole
I6: Four lymph nodes, whole
I7, I8: Multiple lymph nodes, whole

Part J is received fresh labeled with the patient's name, medical record number and as "left neck level 4". The specimen consists of a soft tissue measuring 4 x 3 x 1 cm. Multiple lymph nodes are identified ranging in size from 1.3 x 0.6 x 0.5 cm to 0.5 x 0.5 x 0.5 cm. Representative sections are submitted as described below. (Dictated by

CASSETTE SUMMARY:

J1: Two lymph nodes, whole
J2: Multiple lymph nodes, whole
J3: Three lymph nodes, whole
J4: Multiple lymph nodes, whole

[page 5 of 5]
Part K is received fresh labeled with the patient's name, medical record number and as "left neck contents". The specimen consists of soft tissue measuring 1.8 x 1.0 x 0.6 cm. The specimen is entirely submitted in cassette K1. (Dictated by _____ : note: confirmed with _____ on _____ that this specimen is additional material dissected from level IV)

Intraoperative Consult Diagnosis

A1FS: DEEP, (FROZEN SECTION): NEGATIVE.
B1FS: SUPERIOR, (FROZEN SECTION): NEGATIVE
C1FS: INFERIOR, (FROZEN SECTION): NEGATIVE
D1FS: ANTERIOR, (FROZEN SECTION): FOCAL HIGH GRADE SQUAMOUS DYSPLASIA.
E1FS: POSTERIOR, (FROZEN SECTION): NEGATIVE.
Frozen section results were communicated to the surgical team and were repeated back by _____ on _____

F1FS: ANTERIOR MARGIN (NEW) (FROZEN SECTION): NEGATIVE.
Frozen section results were communicated to the surgical team and were repeated back by _____ on _____

Pathologist:

Microscopic Description

Microscopic examination performed.

Source: NCI Genomic Data Commons file eeb56c2b-4354-4fd2-88e2-0e561b1a2ad3 (TCGA-QK-A6IJ.53C15899-4EC9-4182-945C-DA91A2536E42.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).